Somatic mutation profile of tumor specimen TCGA-TQ-A7RS-01A (aliquot TCGA-TQ-A7RS-01A-12D-A33T-08) from TCGA case TCGA-TQ-A7RS, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 25.1 years (9,172 days).
Specimen TCGA-TQ-A7RS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0224175-6288-4f64-bf8e-2effa05dd9b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RS-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RS-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fb92946-e1d6-41cf-a30f-7ec268854e22

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 11/66 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344635105, COSV50573658; called by muse, mutect2, varscan2
- CIC | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 50/94 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50551766, COSV99359909; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 80/183 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AMMECR1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV99466922; called by muse, mutect2, varscan2
- FBN2 | c.3352G>T p.E1118* | Nonsense Mutation (SNP) | VAF 11/191 reads (6%) | catalogued as COSV52503780, COSV52519067; called by muse, mutect2
- GRIP1 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 71/252 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs141923622; called by muse, mutect2, varscan2
- LSAMP | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.414); catalogued as COSV100371681; called by muse, mutect2
- MPZL2 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 153/358 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs187771174; called by muse, mutect2, varscan2
- NLRP4 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100016657; called by muse, mutect2, varscan2
- PDGFRA | c.1085A>C p.E362A | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99957092; called by muse, mutect2, varscan2
- PXK | c.239T>C p.L80S | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100244216, COSV57094226; called by muse, mutect2
- RYR1 | c.7336G>A p.G2446S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs375148516, COSV100616817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC9A4 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 162/385 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs201264205, COSV54833766; called by muse, mutect2, varscan2
- KIAA1217 | c.5092_5093del p.D1698Ffs*22 | Frame Shift Del (DEL) | VAF 24/166 reads (14%) | called by pindel, varscan2
- NFYA | c.688_695dup p.N232Kfs*10 | Frame Shift Ins (INS) | VAF 59/163 reads (36%) | called by mutect2, varscan2
- FRMD4B | c.2217G>A p.E739= | Silent (SNP) | VAF 76/252 reads (30%) | catalogued as rs770220633, COSV101273532; called by muse, mutect2, varscan2
- SERPINB4 | c.534C>T p.N178= | Silent (SNP) | VAF 91/219 reads (42%) | catalogued as rs763091506, COSV104417763, COSV61984183; called by muse, mutect2, varscan2
- WDR37 | c.924C>T p.Y308= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as rs747325196, COSV99579964; called by muse, mutect2, varscan2
